Somatic mutation profile of tumor specimen TCGA-CR-7391-01A (aliquot TCGA-CR-7391-01A-11D-2012-08) from TCGA case TCGA-CR-7391, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 37.0 years (13,508 days).
Specimen TCGA-CR-7391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88500df6-0a5b-4c2e-997c-10eab38fb25c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7391-10A (Blood Derived Normal), aliquot TCGA-CR-7391-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/151c97c7-119f-4ea8-a7c4-4f7ad16611c9

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD5 | c.1841C>G p.S614C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100429938; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373409868; called by muse, mutect2, varscan2
- EPPK1 | c.708C>T p.R236= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1379570153, COSV101599834; called by muse, mutect2
